CCDI case PBCGDG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/53d7e354-a115-44d3-9279-4d645bc1c17a

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 18.5 years (6,744 days).

Biospecimens (3 samples)
- Sample 0DR6XW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DR6Y7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DR6YH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
